Gene-level copy-number profile of tumor specimen ALCH-B38E-TTP1-A from ALCHEMIST case ALCH-B38E, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.6 years (24,324 days).
Specimen ALCH-B38E-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 00c5b168-6c39-4f53-a033-d1e7af1cd9ea.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B38E-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/41d2140e-ff1b-4d1a-9941-f03ad7ebd4f2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 114; copy number 2: 54,001; copy number 3: 4,272; copy number 4: 5; copy number 5: 4; copy number 9: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,712,572–136,724,742, 1 gene, copy number 5 (within-gene range 2–5): DIPK1B.
- chr11:1,776,930–1,778,388, 1 gene, copy number 9: AC068580.2.
- chr19:1,248,553–1,274,880, 3 genes, copy number 5: MIDN, CIRBP, CIRBP-AS1.

Autosomal genes at a single copy (total copy number 1): 113. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
